Somatic mutation profile of tumor specimen MMRF_2692_1_BM_CD138pos (aliquot MMRF_2692_1_BM_CD138pos_T1_KHS5U_L14418) from MMRF case MMRF_2692, project MMRF-COMMPASS (Multiple Myeloma CoMMpass Study). Sex at birth: female; Vital status: Dead; Primary diagnosis: Multiple myeloma; Tissue or organ of origin: Bone marrow; Age at diagnosis: 43.5 years (15,879 days).
Specimen MMRF_2692_1_BM_CD138pos: Sample type: Primary Blood Derived Cancer - Bone Marrow; Tissue type: Tumor; Tumor descriptor: Primary; Specimen type: Bone Marrow NOS.
Source: NCI Genomic Data Commons open-access Masked Somatic Mutation file (Mutation Annotation Format, MAF) 2710b15f-027e-4112-9d55-a6b4332060c9.wxs.aliquot_ensemble_masked.maf.gz, workflow Aliquot Ensemble Somatic Variant Merging and Masking; Data Release 46.0 - August 10, 2026. Variants were called in the tumor against matched normal specimen MMRF_2692_1_PB_WBC (Blood Derived Normal), aliquot MMRF_2692_1_PB_WBC_C2_KHS5U_L14419; read counts below are tumor reads.
https://portal.gdc.cancer.gov/files/d2866e22-8414-4c05-b72a-84d1c8ee9ceb

The open-access MAF lists 2 somatic variants for this specimen: 2 other (UTR, intronic, flanking, RNA and similar).
By variant classification: 3'UTR 2.

Variants (all; order: hotspot or ClinVar-pathogenic variants first, then other protein-altering variants with a dbSNP/COSMIC/ClinVar record ('catalogued as' / 'ClinVar'), then the remaining protein-altering, then silent, then non-coding — alphabetical by gene within each group; each line: gene | DNA and protein change | classification | tumor variant allele fraction (VAF) | annotations). Protein positions are numbered on GDC's canonical Ensembl transcript (GENCODE v36); where an older RefSeq transcript numbers the protein differently, the line names both transcripts and gives that numbering too:
- IGFBP5 | c.*221del | 3'UTR (DEL) | VAF 10/76 reads (13%) | catalogued as rs6413496; called by mutect2, varscan2
- NCOA3 | c.*835A>T | 3'UTR (SNP) | VAF 6/90 reads (7%) | catalogued as rs1252012997, COSV100507196; called by muse, mutect2
